TCGA case TCGA-HR-A2OG — Skin Cutaneous Melanoma (TCGA-SKCM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Skin; Tissue source site: Ontario Institute for Cancer Research (OICR). Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/021d32b0-a94a-4dad-95f4-8eb0abd894bf

Demographics
Sex at birth: female; Country of residence at enrollment: Canada; Age at index: 59 years; Vital status: Alive.

Diagnoses (2)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C44.6; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin of upper limb and shoulder; Classification of tumor: metastasis; Age at diagnosis: 59.6 years (21,767 days); Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 7 days; Melanoma known primary: Yes.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; Pharmaceutical Therapy, NOS, prior to procurement; adjuvant Radiation Therapy, NOS; Radiation Therapy, NOS, prior to procurement.
2. Malignant melanoma, NOS: Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Sites of involvement: Skin, Extremities.
   Recorded as not given: Radiation Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 7 days; Disease response: Tumor Free.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-HR-A2OG-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-HR-A2OG-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Initial weight: 340 mg.
  Slide TCGA-HR-A2OG-06A-02-TSB: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-HR-A2OG-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Radiation therapy to primary: No; Primary location: Distant Metastasis; Metastatic tumor site: Right Thigh (Subcutaneous Tissue); Primary melanoma skin type: Non-glabrous skin; Prior radiation therapy: No; History neoadjuvant treatment: No.
- Sites of primary melanomas: Primary multiple at diagnosis: No.
- Sites of primary melanomas, Site: Submitted tumor site: Extremities; Melanoma primary count: 1.
- Follow-up form: Lost to follow-up: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 7 days; disease-specific survival: no event (censored), 7 days; progression-free interval: no event (censored), 7 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-HR-A2OG-01): tumor purity 0.41, ploidy 3.93, whole-genome doublings 2 (call status: maf_call).
